PECGS case C083-000064 — USC PE-CGS: Optimizing Engagement of Hispanic Colorectal Cancer Patients in Cancer Genomic Characterization Studies (PECGS-COPECC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectum. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/ad0f71f0-2dc9-49c7-bcf2-0cbcaefcc413

Demographics
Sex at birth: female; Age at index: 56 years; Year of birth: 1964; Education level: Vocational College or Some College.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Rectum, NOS; Age at diagnosis: 55.5 years (20,271 days); AJCC clinical stage: Stage IIIB; AJCC pathologic stage: Stage IIIC; Progression or recurrence: yes; Days to last follow up: 281 days.

Other clinical attributes
- Menopause status: Postmenopausal.

Biospecimens (2 samples)
- Sample C083-000064_Germline: Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample C083-000064_Tumor: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
